Somatic mutation profile of tumor specimen 0DJPCX from CCDI case PBBXAN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.6 years (3,129 days).
Specimen 0DJPCX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e4943c5-88bc-4cd1-a80f-d4668186fb8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJPCM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f68bad63-5e2c-4752-a337-60de3ee7d03a

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GUCY2F | c.2938C>T p.R980* | Nonsense Mutation (SNP) | VAF 64/380 reads (17%) | catalogued as rs767389454, COSV54306635, COSV99485743; called by muse, varscan2
- OR8B12 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 156/453 reads (34%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs146463957; called by muse, varscan2
- ATRX | c.3477G>A p.E1159= | Silent (SNP) | VAF 76/440 reads (17%) | called by muse, varscan2
